Somatic mutation profile of tumor specimen TCGA-CJ-4908-01A (aliquot TCGA-CJ-4908-01A-01D-1429-08) from TCGA case TCGA-CJ-4908, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 38.9 years (14,226 days).
Specimen TCGA-CJ-4908-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a6bbd5-2581-4158-9e10-a58749d16148.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4908-11A (Solid Tissue Normal), aliquot TCGA-CJ-4908-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12ab4913-9d79-4710-8986-c95685ffb110

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.444del p.F148Lfs*11 | Frame Shift Del (DEL) | VAF 71/293 reads (24%) | catalogued as rs869025653, CM982009; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.4726G>A p.E1576K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57061364; called by muse, mutect2, varscan2
- ACP2 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV57041030; called by muse, mutect2
- ACSS2 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV53626301, COSV53628841; called by muse, mutect2, varscan2
- ACTBL2 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as COSV70661899; called by muse, mutect2, varscan2
- ARHGEF3 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56333512; called by muse, mutect2, varscan2
- CFAP43 | c.2213C>A p.A738D | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV53380904, COSV53382096; called by muse, mutect2, varscan2
- CNGA4 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV66005928, COSV66007267; called by muse, varscan2
- DDX10 | c.2474T>C p.M825T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV59441458; called by muse, mutect2
- IGFN1 | c.2693C>A p.T898N (on ENST00000295591 / NM_001367841.1; = p.T3355N on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV55180928; called by muse, mutect2, varscan2
- IRAG1 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV70213245; called by muse, mutect2
- KANSL2 | c.1361T>G p.M454R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as COSV67611185; called by muse, mutect2, varscan2
- MLLT1 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53133810; called by muse, mutect2, varscan2
- MXRA7 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 45/222 reads (20%) | PolyPhen probably damaging (0.988); catalogued as COSV63322154; called by muse, mutect2, varscan2
- NELFE | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV64814756; called by muse, mutect2, varscan2
- PBRM1 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV56309113; called by muse, mutect2, varscan2
- SCRN2 | c.34T>A p.C12S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51637653; called by muse, mutect2, varscan2
- SEMA4D | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59392020; called by muse, mutect2, varscan2
- TSEN2 | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53191438; called by muse, mutect2
- VSIG1 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV54262876; called by muse, mutect2, varscan2
- ZMYM6 | c.2015T>A p.M672K | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV64122853; called by muse, mutect2, varscan2
- NUP205 | c.3099del p.H1034Tfs*4 | Frame Shift Del (DEL) | VAF 26/157 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.1059G>A p.S353= | Silent (SNP) | VAF 19/306 reads (6%) | catalogued as rs374122138; called by muse, mutect2
- CUBN | c.9837T>C p.G3279= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64729356; called by muse, mutect2, varscan2
- GRK2 | c.1257T>C p.P419= | Silent (SNP) | VAF 71/290 reads (24%) | catalogued as COSV57954476; called by muse, mutect2, varscan2
- KANSL1 | c.1098A>G p.G366= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as COSV52275225; called by muse, mutect2, varscan2
- LRIF1 | c.1026T>A p.P342= | Silent (SNP) | VAF 58/261 reads (22%) | catalogued as COSV63898580; called by muse, mutect2, varscan2
- SLC35A1 | c.447T>C p.F149= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs1393933656, COSV65780811; called by muse, mutect2, varscan2
- SUPT6H | c.4062T>C p.D1354= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as COSV58932242; called by muse, mutect2, varscan2
- ZSCAN16 | c.*3_*4del | Silent (DEL) | VAF 14/98 reads (14%) | called by pindel, varscan2
- FGFR3 | c.*965G>T | 3'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53423577; called by muse, mutect2, varscan2
- MRPL39 | c.969+1108del | Intron (DEL) | VAF 8/72 reads (11%) | catalogued as COSV56259995; called by mutect2, pindel, varscan2
- VPS28 | c.549-11T>G | Intron (SNP) | VAF 30/148 reads (20%) | catalogued as COSV52873864; called by muse, mutect2, varscan2
